Gene-level copy-number profile of tumor specimen TCGA-W5-AA39-01A from TCGA case TCGA-W5-AA39, project TCGA-CHOL (Cholangiocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Cholangiocarcinoma; Tissue or organ of origin: Intrahepatic bile duct; AJCC pathologic stage: Stage II; Tumor grade: G4; Age at diagnosis: 81.0 years (29,594 days).
Specimen TCGA-W5-AA39-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CHOL.634b12f9-51f3-4c06-bbf5-162c2519e33a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-W5-AA39-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e3e4fa36-f21a-450d-8c89-bcb37a399136

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 7,557; copy number 2: 41,133; copy number 3: 7,801; copy number 4: 2,058; copy number 5: 546; copy number 6: 710.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-W5-AA39-01A-11D-A416-01): tumor purity 0.87, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:16,802,651–17,090,604, 3 genes (within-gene range 0–1): PLCL2, MIR3714, PLCL2-AS1.
- chr4:134,383,467–135,123,779, 8 genes (within-gene range 0–1): LINC02462, AC093722.1, AC104619.2, AC104619.4, AC104619.1, AC104619.3, AC107463.1, LINC02485.
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,256 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:227,234,269–248,919,946, 546 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,172. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
